CGCI case BLGSP-71-23-00456 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78711550-eef8-4afe-ba85-0677d530258a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,020 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,448 days (4.0 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Bone marrow / Liver.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Tumor largest dimension diameter: 23.5 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 1,448 days (4.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- IRF4 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 5357 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 56 kg; Height: 165 cm; BMI: 20.6; CD4 count: 55; Haart treatment indicator: Yes.
- Day 0: Cdc hiv risk factors: Transfusion Recipient.
- Day 0: Risk factors: HIV/AIDS.
- Day 0: Comorbidities: HIV/AIDS.
- Day 1,448: Nadir CD4 count: 203.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00456-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 25; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-23-00456-01A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 25; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-23-00456-01A-02-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00456-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00456-01-BCL6: Tissue microarray coordinates: C2,F3,B5.
  Slide BLGSP-71-23-00456-01-CD10: Tissue microarray coordinates: C2,F3,B5.
  Slide BLGSP-71-23-00456-01-BCL2: Tissue microarray coordinates: C2,F3,B5.
  Slide BLGSP-71-23-00456-01-CD20: Tissue microarray coordinates: C2,F3,B5.
  Slide BLGSP-71-23-00456-01-CD3: Tissue microarray coordinates: C2,F3,B5.
  Slide BLGSP-71-23-00456-01-Ki67: Tissue microarray coordinates: C2,F3,B5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- History of disease: HPV test results: Equivocal; Kshv hhv8 test results: Inconclusive; Haart therapy at diagnosis: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Liver.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Tests performed: LDH level: 5357; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: MUM-1.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
